Somatic mutation profile of tumor specimen TCGA-WB-A80Y-01A (aliquot TCGA-WB-A80Y-01A-11D-A35I-08) from TCGA case TCGA-WB-A80Y, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 60.0 years (21,902 days).
Specimen TCGA-WB-A80Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b41ce80b-caf1-44e3-86a6-74745685d3c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WB-A80Y-10A (Blood Derived Normal), aliquot TCGA-WB-A80Y-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/379ea415-22c8-4d3a-bf4a-f0ac0dc2be23

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CPT1C | c.923A>G p.E308G | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- DSTYK | c.820T>C p.F274L | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.94); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DYNC2H1 | c.3890A>G p.D1297G | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- LIG1 | c.844A>G p.K282E | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PSD3 | c.2231A>G p.E744G (on ENST00000440756; = p.E743G on NM_015310.4) | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- CCDC39 | c.1333T>C p.L445= | Silent (SNP) | VAF 7/23 reads (30%) | called by muse, mutect2
